TCGA case TCGA-74-6573 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Swedish Neurosciences. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8d0d7a7e-8fae-437d-9b39-f2f17d0f5e4f

Demographics
Sex at birth: male; Age at index: 67 years; Vital status: Dead; Days to death: 105 days.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 67.4 years (24,632 days); Year of diagnosis: 2009; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 24 days; Days to treatment end: 66 days; Treatment dose: 5,800 cGy; Course number: 1; Number of fractions: 35; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 24 days; Days to treatment end: 66 days; Number of cycles: 1; Treatment dose: 6,020 mg; Prescribed dose: 140; Prescribed dose units: mg/day; Route of administration: Oral.

Follow-up (3 entries)
- Days to follow up: 105 days; Disease response: With Tumor.
- Karnofsky performance status: 0; Timepoint: Post Adjuvant Therapy.
- Karnofsky performance status: 100; Timepoint: Preoperative.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-74-6573-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.8; Intermediate dimension: 0.9; Shortest dimension: 0.6.
  Slide TCGA-74-6573-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 40; Percent stromal cells: 0.
  Slide TCGA-74-6573-01A-01-BS1: Section location: Bottom; Percent tumor cells: 82; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 18; Percent stromal cells: 0.
- Sample TCGA-74-6573-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.1; Intermediate dimension: 0.6; Shortest dimension: 0.5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment: Regimen number: 1.
- Drug treatment, Route of administrations: Route of administration: PO.
- Follow-up form 1: Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 105 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 105 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 105 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-74-6573-01A-12D-1842-01): tumor purity 0.86, ploidy 1.91, whole-genome doublings 0.
